Somatic mutation profile of tumor specimen MMRF_2011_2_BM_CD138pos (aliquot MMRF_2011_2_BM_CD138pos_T1_KHS5U_L16522) from MMRF case MMRF_2011, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.7 years (26,913 days).
Specimen MMRF_2011_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34265989-a292-4833-ad15-e0892019d191.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2011_2_PB_WBC (Blood Derived Normal), aliquot MMRF_2011_2_PB_WBC_C2_KHS5U_L16594; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99b7cdb6-4568-4d0f-80ca-01be79f9c497

The open-access MAF lists 46 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 9, 3'UTR 5, Intron 4, Nonsense Mutation 2, 3'Flank 2, RNA 2, Splice Site 2, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BNC2 | c.56A>G p.D19G | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.003); catalogued as COSV66156772; called by muse, mutect2, varscan2
- CELSR1 | c.1174G>A p.V392M | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs1486743335, COSV53089255; called by muse, mutect2
- FBXL14 | c.652C>A p.L218I | Missense Mutation (SNP) | VAF 33/314 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as rs752706841; called by muse, mutect2, varscan2
- HK1 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV53861606; called by muse, mutect2
- IGHV2-70 | c.94A>G p.K32E | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751761340; called by muse, varscan2
- IGHV4-34 | c.206A>G p.K69R | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.324); catalogued as rs587616360; called by muse, mutect2, varscan2
- IGLV3-1 | c.311A>T p.Y104F | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs142180628; called by muse, mutect2, varscan2
- IL18RAP | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 11/100 reads (11%) | catalogued as rs369615964; called by muse, mutect2
- NFAT5 | c.1134G>A p.M378I | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100590868; called by muse, mutect2, varscan2
- PARD3B | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62509030; called by muse, mutect2, varscan2
- ABCC8 | c.1583A>T p.K528M | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ADGRG2 | c.718C>T p.Q240* (on ENST00000379869 / NM_001079858.3; = p.Q237* on NM_005756.4) | Nonsense Mutation (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- CCSER1 | c.2219C>A p.A740D | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- CES5A | c.1600C>A p.P534T (on ENST00000290567 / NM_001143685.2; = p.P484T on NM_145024.3) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- COL22A1 | c.3286-2A>G p.X1096_splice | Splice Site (SNP) | VAF 25/189 reads (13%) | called by muse, mutect2, varscan2
- CXCR5 | c.250A>T p.S84C | Missense Mutation (SNP) | VAF 21/253 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- GLI3 | c.2812G>A p.G938R | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HCFC2 | c.874+2T>C p.X292_splice | Splice Site (SNP) | VAF 21/138 reads (15%) | called by muse, mutect2, varscan2
- HNRNPCL1 | c.629A>T p.K210I | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYO5C | c.4424A>C p.N1475T | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- NTNG2 | c.593A>G p.E198G | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- SPEF2 | c.3106A>G p.N1036D | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.058); called by muse, mutect2
- ZNF791 | c.600del p.S201Vfs*60 | Frame Shift Del (DEL) | VAF 45/439 reads (10%) | called by mutect2, pindel, varscan2
- IQCF1 | c.507C>T p.I169= | Silent (SNP) | VAF 31/245 reads (13%) | catalogued as COSV58823202; called by muse, mutect2, varscan2
- MYOM1 | c.2535C>T p.P845= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs1307620327; called by muse, mutect2
- NECAB1 | c.147A>G p.E49= | Silent (SNP) | VAF 4/61 reads (7%) | called by muse, mutect2
- RC3H1 | c.3108C>T p.I1036= | Silent (SNP) | VAF 18/138 reads (13%) | catalogued as rs753016379; called by muse, mutect2, varscan2
- SLCO5A1 | c.1707C>G p.V569= | Silent (SNP) | VAF 16/139 reads (12%) | catalogued as COSV99481535; called by muse, mutect2, varscan2
- SOCS7 | c.759C>T p.P253= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs1269541194; called by muse, mutect2, varscan2
- STK31 | c.2913T>C p.C971= | Silent (SNP) | VAF 6/67 reads (9%) | called by muse, mutect2
- TMEM119 | c.582G>A p.G194= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs759634362; called by muse, mutect2, varscan2
- ZNF582 | c.171C>T p.F57= | Silent (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2
- AC093802.1 | n.1914+8201C>T | Intron (SNP) | VAF 16/348 reads (5%) | catalogued as rs1278625006; called by muse, mutect2
- ASAP3 | c.*170G>A | 3'UTR (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- C1S | c.872-30del | Intron (DEL) | VAF 7/87 reads (8%) | called by mutect2, pindel
- CBY1 | c.-38-74_-38-52del | Intron (DEL) | VAF 19/203 reads (9%) | called by mutect2, pindel
- DGKA | c.350-120A>T | Intron (SNP) | VAF 14/110 reads (13%) | called by muse, mutect2, varscan2
- MAP9 | c.*3114T>C | 3'UTR (SNP) | VAF 6/142 reads (4%) | called by muse, mutect2
- MIR4286 | n.93G>A | RNA (SNP) | VAF 21/224 reads (9%) | called by muse, mutect2
- PLCB1 | c.*1292T>A | 3'UTR (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- RIMS1 | chr6:72401616 C>T | 3'Flank (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- SEL1L3 | chr4:25863535 G>A | 5'Flank (SNP) | VAF 24/201 reads (12%) | catalogued as rs1283260195; called by muse, mutect2, varscan2
- ST8SIA2 | chr15:92472488 T>C | 3'Flank (SNP) | VAF 21/164 reads (13%) | called by muse, mutect2, varscan2
- TMEM70 | c.*630G>A | 3'UTR (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- TXLNGY | n.6240C>T | RNA (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- USP1 | c.*291C>T | 3'UTR (SNP) | VAF 8/92 reads (9%) | catalogued as rs978940749; called by muse, mutect2
